TCGA case TCGA-AP-A05D — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f7e06a10-74ca-4f52-a944-b3f22c016998

Demographics
Sex at birth: female; Race: white; Age at index: 67 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 67.3 years (24,597 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; FIGO stage: Stage IIIC2; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,758 days (4.8 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 1; Lymph nodes tested: 29.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 73.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 1; Lymph nodes tested: 8.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 99 days; Days to treatment end: 134 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 100 days; Days to treatment end: 127 days; Number of cycles: 5; Treatment dose: 395 mg; Prescribed dose: 40; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 135 days; Days to treatment end: 139 days; Treatment dose: 540 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 194 days; Days to treatment end: 259 days; Number of cycles: 4; Treatment dose: 2,165 mg; Prescribed dose: 5; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 194 days; Days to treatment end: 259 days; Number of cycles: 4; Treatment dose: 1,380 mg; Prescribed dose: 175; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Classification of tumor: Prior primary; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,364 days (3.7 years); Disease response: Tumor Free.
- Days to follow up: 1,758 days (4.8 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 98 kg; Height: 161 cm; BMI: 37.8.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: Yes; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Cancer / Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AP-A05D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-AP-A05D-01A-01-BS1: Section location: Bottom; Percent tumor cells: 84; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 15; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AP-A05D-01A-01-TS1: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 20; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AP-A05D-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AP-A05D-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open; Lymph nodes pelvic pos by IHC: 0; Lymph nodes aortic pos by IHC: 0.
- Follow-up form 1: History menopausal hormone therapy: Yes, I have taken menopausal hormone therapy in the past, but no longer do; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 2; History colorectal cancer: Yes; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.
- Follow-up form 2: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Rectum; Other malignancy histological type: Rectal Adenocarcinoma.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -344.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: from Jay Bowen/NWCH.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,758 days; disease-specific survival: no event (censored), 1,758 days; disease-free interval: no event (censored), 1,758 days; progression-free interval: no event (censored), 1,758 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AP-A05D-01A-11D-A00X-01): tumor purity 0.68, ploidy 3.57, whole-genome doublings 1.
